Somatic mutation profile of tumor specimen 43192517-085e-450e-9481-0a6713 (aliquot 43192517-085e-450e-9481-0a6713_D6_2) from CPTAC case 05CO054, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 43192517-085e-450e-9481-0a6713: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cec51db3-a29c-42a3-a5fa-d6c2bb717856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen be329c23-0f98-494d-b489-9047e9 (Blood Derived Normal), aliquot be329c23-0f98-494d-b489-9047e9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1965549d-49d1-47b2-a720-4bb3e549d30d

The open-access MAF lists 352 somatic variants for this specimen: 221 protein-altering or splice-affecting, 93 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 93, Nonsense Mutation 20, Intron 18, 3'UTR 7, Splice Site 7, Frame Shift Del 6, RNA 6, 5'UTR 5, Frame Shift Ins 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSND | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315285, CM013302, COSV64870733; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- COL1A1 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 143/479 reads (30%) | catalogued as rs72651642, CM960322; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72658143, CM011304, COSV51952372; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 38/169 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 78/398 reads (20%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by mutect2, varscan2
- AC105001.2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1242341959; called by muse, mutect2, varscan2
- AKAP17A | c.1152+5C>T | Splice Region (SNP) | VAF 20/190 reads (11%) | catalogued as rs1372704811; called by muse, mutect2, varscan2
- ANXA11 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs139186583; called by muse, mutect2
- APC | c.4455del p.D1486Ifs*21 | Frame Shift Del (DEL) | VAF 93/209 reads (44%) | catalogued as COSV57321956; called by mutect2, pindel, varscan2
- ARID1B | c.5435A>G p.D1812G | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV51653482; called by muse, mutect2, varscan2
- ATRN | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs267605919, COSV53523155; called by muse, mutect2
- B3GNTL1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs759872616, COSV104413837; called by mutect2, varscan2
- C8B | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs147180727; called by muse, mutect2, varscan2
- CACNA1I | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs775581201, COSV100360944, COSV60810611; called by muse, mutect2, varscan2
- CACNG6 | c.701G>T p.G234V (on ENST00000252729 / NM_145814.1; = p.G163V on NM_031897.2) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99403597; called by muse, mutect2, varscan2
- CBX4 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762486081, COSV53967958; called by muse, varscan2
- CFAP221 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs556658192, COSV54658547; called by muse, mutect2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHD3 | c.5521G>A p.E1841K (on ENST00000330494 / NM_001005273.3; = p.E1807K on NM_005852.4) | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313938382; called by muse, mutect2, varscan2
- CLCN3 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs1249693885, COSV61626361; called by muse, mutect2, varscan2
- CLEC17A | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60429443; called by muse, mutect2, varscan2
- CNTN1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | catalogued as COSV61640104; called by muse, mutect2
- COL1A2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 65/760 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51954105; called by muse, mutect2
- COL27A1 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 50/473 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762317284; called by muse, mutect2, varscan2
- COLQ | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 42/182 reads (23%) | catalogued as rs143766249, COSV67524686; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CPXM2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.18); catalogued as rs1426414905, COSV99583540; called by muse, mutect2, varscan2
- DDX51 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752191507, COSV100223275; called by muse, mutect2, varscan2
- DIXDC1 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67742998; called by muse, mutect2, varscan2
- DYTN | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs771372596, COSV65970779; called by muse, mutect2
- DZIP1L | c.1747A>G p.S583G | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59521633; called by muse, mutect2
- EFEMP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779247685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENTR1 | c.713G>A p.R238H (on ENST00000357365 / NM_001039707.2; = p.R215H on NM_006643.4) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs761319963, COSV53740796; called by muse, mutect2, varscan2
- EYA4 | c.1241G>A p.R414H (on ENST00000531901 / NM_001301013.1; = p.R408H on NM_004100.5) | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs760787542, COSV62047993, COSV62049072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM171A2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219709374; called by muse, mutect2
- FAM90A10P | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 39/420 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1375790422; called by muse, mutect2
- FAT4 | c.11209C>T p.R3737C | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs747382793, COSV58671640; called by muse, mutect2, varscan2
- FBXW7 | c.1427G>A p.S476N (on ENST00000281708 / NM_001349798.2; = p.S396N on NM_018315.5) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55890941, COSV55916432; called by muse, mutect2, varscan2
- FERD3L | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51761969, COSV51764235; called by muse, mutect2
- FMO3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV63007700; called by muse, mutect2, varscan2
- FRMD6 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1254831669, COSV100655473; called by muse, mutect2
- FYB2 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV58590637; called by muse, mutect2, varscan2
- GALNT17 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.056); catalogued as rs772102107, COSV61152262; called by muse, mutect2
- GAS7 | c.1018C>T p.R340W (on ENST00000432992 / NM_201433.2; = p.R200W on NM_003644.3) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs142502537; called by muse, mutect2, varscan2
- GLB1L3 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253603300; called by muse, mutect2, varscan2
- GLUD2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200880803, COSV60151559, COSV60152177; called by muse, mutect2, varscan2
- GOLGB1 | c.4665G>T p.M1555I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61472829; called by muse, mutect2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by mutect2, varscan2
- HECW2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745762497; called by muse, mutect2
- HEG1 | c.3760G>C p.A1254P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767092978; called by muse, mutect2, varscan2
- HS1BP3 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs190813407; called by muse, mutect2
- HS3ST2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746835350, COSV54457793; called by muse, mutect2, varscan2
- HTR1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 46/467 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs1260684033, COSV60499881; called by muse, mutect2
- IL10RA | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs747574092; called by muse, mutect2, varscan2
- IQCA1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54502661; called by muse, mutect2, varscan2
- KCNA5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as rs140711603; called by muse, mutect2
- KCNMB1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.734); catalogued as rs775722063; called by muse, mutect2, varscan2
- KIF15 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs149974125; called by muse, mutect2, varscan2
- KPRP | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs150045632; called by muse, mutect2, varscan2
- KSR2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1421037103, COSV60395845; called by muse, mutect2, varscan2
- LDB3 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs758182278; ClinVar: uncertain significance; called by muse, mutect2
- LRRC7 | c.166C>T p.R56* (on ENST00000651989 / NM_001370785.2; = p.R23* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/302 reads (8%) | catalogued as rs767787912, COSV50634200, COSV99226712; called by muse, mutect2
- MAGEC1 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV53580618; called by muse, mutect2
- MAP2K4 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1208900089, COSV62258825, COSV62261287; called by muse, mutect2, varscan2
- MARCHF2 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs202077510; called by muse, mutect2, varscan2
- MASP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775120367, COSV68896171; called by muse, mutect2, varscan2
- MAST2 | c.5279G>A p.R1760Q | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs545752601; called by muse, mutect2, varscan2
- MAST3 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs745945880; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | catalogued as rs1180255648; called by mutect2, pindel
- MFAP4 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs369216051; called by muse, mutect2, varscan2
- MMP27 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1565426667; called by muse, mutect2
- NCCRP1 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs544307213; called by muse, mutect2
- NLRP12 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as rs1319286947, COSV60746443; called by muse, mutect2, varscan2
- NYNRIN | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs775804688, COSV66844047; called by muse, mutect2, varscan2
- OLFM3 | c.1032C>A p.F344L (on ENST00000338858 / NM_001288821.1; = p.F324L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100130059, COSV58803119; called by muse, mutect2, varscan2
- OPCML | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs767079791, COSV59455705; called by muse, mutect2, varscan2
- OPCML | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs374001465; called by muse, mutect2, varscan2
- OR8I2 | c.308T>A p.F103Y | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV56170916; called by muse, mutect2, varscan2
- OR9K2 | c.422C>T p.A141V (on ENST00000305377; = p.A119V on NM_001005243.1) | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs138102893, COSV59531898; called by muse, mutect2, varscan2
- PCDH15 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100217698; called by muse, mutect2, varscan2
- PCDHA13 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV56532125; called by muse, mutect2, varscan2
- PCDHGA11 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs371027437, COSV53984701; called by muse, mutect2, varscan2
- PCDHGA11 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.185); catalogued as rs202010010; called by muse, mutect2, varscan2
- PCDHGA3 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as rs865822045; called by muse, mutect2
- PKHD1 | c.10445G>A p.R3482H | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs143915416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLD3 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as rs1313886181, CM140823, COSV62924179; called by muse, mutect2, varscan2
- PLXNB1 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746314397, COSV56492454; called by muse, mutect2
- PREX1 | c.4810C>T p.R1604W | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447178153, COSV64249860; called by muse, mutect2, varscan2
- PRICKLE1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs146670726, CM119665; called by muse, mutect2, varscan2
- PSMA8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV57603946; called by muse, mutect2, varscan2
- PTPRN2 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66104992; called by muse, mutect2
- RBMXL2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV60978776; called by muse, mutect2, varscan2
- RBSN | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as rs776101358, COSV53794669; called by muse, mutect2
- RELN | c.48G>T p.L16F | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1563128080; called by muse, varscan2
- ROBO2 | c.2213C>G p.A738G | Missense Mutation (SNP) | VAF 31/375 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.229); catalogued as rs750635483; called by muse, mutect2
- RYR2 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs564869863, COSV63679506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.7792G>A p.E2598K | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV66544184; called by muse, mutect2
- SALL3 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV73306041; called by muse, mutect2, varscan2
- SCARA3 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs767662250, COSV57269235; called by muse, mutect2, varscan2
- SFN | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV59433782; called by muse, mutect2, varscan2
- SLC30A8 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1157644561; called by muse, mutect2
- SLC35A4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745807178, COSV60053506; called by muse, mutect2, varscan2
- SLC7A7 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs1165853447; called by muse, mutect2
- SOHLH2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs758411552; called by muse, mutect2, varscan2
- SORCS2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs373293446; called by muse, mutect2, varscan2
- SOS1 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67676494; called by muse, mutect2
- SRCAP | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs570867665; called by muse, mutect2
- SYT16 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777540095, COSV70856141; called by muse, mutect2, varscan2
- TAS1R2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 58/678 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs771595070, COSV64747276; called by muse, mutect2
- THOC7 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1454490174, COSV99890105; called by muse, mutect2, varscan2
- TMCC2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs745951886, COSV58002673; called by muse, mutect2, varscan2
- TMEM132D | c.3088C>T p.Q1030* | Nonsense Mutation (SNP) | VAF 55/225 reads (24%) | catalogued as COSV67159760; called by muse, mutect2, varscan2
- TNRC6B | c.1828C>T p.R610* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | catalogued as rs766803637; called by muse, mutect2, varscan2
- TRABD2A | c.1268G>A p.R423Q (on ENST00000409520 / NM_001277053.2; = p.R374Q on NM_001080824.3) | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs562954319; called by muse, mutect2, varscan2
- TRMT9B | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs375459091, COSV67947794; called by muse, mutect2, varscan2
- USP28 | c.3178C>T p.R1060* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs369694271; called by mutect2, varscan2
- VANGL2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 102/601 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1341796265, COSV63604133; called by muse, mutect2, varscan2
- VCL | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215494764, CM137779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWC2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as rs937348341, COSV100514480; called by muse, mutect2
- WDR73 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs774735599, COSV62411254; called by muse, mutect2
- WNT5B | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs367856456; called by muse, mutect2, varscan2
- XYLT1 | c.1644C>A p.N548K | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV54491796; called by muse, mutect2, varscan2
- ZNF195 | c.814C>A p.Q272K (on ENST00000399602 / NM_001130520.3; = p.Q200K on NM_007152.5) | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50001784; called by muse, mutect2, varscan2
- ZNF517 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1273355544; called by muse, mutect2
- ACTG1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.349); called by muse, varscan2
- ACTRT1 | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- AEBP1 | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALB | c.453T>A p.F151L | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by mutect2, varscan2
- ALDH1A2 | c.1087-1G>C p.X363_splice | Splice Site (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- ALG1 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALX1 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANK1 | c.5146G>A p.A1716T | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.118); called by muse, mutect2
- ARHGAP20 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ARL13B | c.1150G>A p.G384R (on ENST00000394222 / NM_001174150.2; = p.G277R on NM_144996.4) | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ARPP21 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- BRCA2 | c.8755G>T p.G2919C | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.366); called by muse, mutect2
- BRF1 | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C9orf50 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- CACNA1H | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPRIN1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2
- CARD14 | c.1993C>A p.L665I | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- CARTPT | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 110/593 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CASP8AP2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CBY2 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 125/683 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CCDC80 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, varscan2
- CDH19 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CLEC4F | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CP | c.636T>A p.H212Q | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CRISPLD2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- CYP2C9 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDOST | c.1064T>C p.L355P (on ENST00000415136; = p.L338P on NM_005216.5) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DGCR8 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.1730_1731del p.K577Rfs*10 (on ENST00000445597; = p.K558Rfs*10 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 13/139 reads (9%) | called by mutect2, pindel
- DSCAM | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM227B | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAT3 | c.12456G>T p.K4152N | Missense Mutation (SNP) | VAF 60/726 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.134); called by muse, mutect2
- FBXW7 | c.1619A>T p.H540L (on ENST00000281708 / NM_001349798.2; = p.H460L on NM_018315.5) | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXF2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GAS2L2 | c.2296_2297del p.K766Efs*23 | Frame Shift Del (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- GC | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GLI3 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HERC2 | c.11823del p.D3942Mfs*49 | Frame Shift Del (DEL) | VAF 32/244 reads (13%) | called by mutect2, pindel, varscan2
- HTR7 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- INO80 | c.313+1G>T p.X105_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- KCNH2 | c.3331-2A>T p.X1111_splice | Splice Site (SNP) | VAF 29/388 reads (7%) | called by muse, mutect2
- KCNS1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- KMT2C | c.6242C>T p.P2081L | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- KRTAP20-3 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2
- KSR2 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- LGR5 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2
- MACROD2 | c.869G>T p.G290V (on ENST00000642719; = p.G262V on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- MACROH2A2 | c.1103A>G p.K368R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.93); called by muse, varscan2
- MAP4K1 | c.418-4C>T | Splice Region (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- ME3 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- MIA2 | c.425_426dup p.P143Ifs*20 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- MMP12 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NELL1 | c.2019C>A p.C673* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- OR2C1 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 55/424 reads (13%) | called by muse, mutect2, varscan2
- OR2W3 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ORC4 | c.79A>T p.R27* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- ORC4 | c.78A>C p.E26D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OSBPL10 | c.1737G>T p.R579S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, varscan2
- PDE8A | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- PHTF2 | c.1498C>A p.Q500K (on ENST00000248550 / NM_001366089.1; = p.Q462K on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PIK3R5 | c.1212G>C p.W404C | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PIKFYVE | c.4471A>G p.I1491V | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLPPR5 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PROSER3 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PRPF8 | c.2150G>A p.W717* | Nonsense Mutation (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- PRPSAP1 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSMD1 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RASA1 | c.41dup p.T15Nfs*97 | Frame Shift Ins (INS) | VAF 24/190 reads (13%) | called by mutect2, varscan2
- ROS1 | c.4555G>T p.D1519Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RPS26 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2
- SASS6 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SHLD3 | c.41G>C p.S14T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SLC26A8 | c.2472+2T>C p.X824_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2
- SLC27A6 | c.1601C>G p.T534R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- SLC34A1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- SLC46A2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2
- SLC7A9 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- SLX4 | c.3026G>A p.G1009D | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- SMARCA4 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- SMC1A | c.1255-2A>G p.X419_splice | Splice Site (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- SNX2 | c.1040G>C p.S347T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SOX9 | c.1177del p.Q393Sfs*10 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- STAG2 | c.2674-6_2674-2del p.X892_splice | Splice Site (DEL) | VAF 17/29 reads (59%) | called by mutect2, pindel, varscan2
- STING1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.194); called by muse, mutect2
- STIP1 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUV39H1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACC2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- TAFA1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- TDRD6 | c.5932G>T p.E1978* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TGIF1 | c.26C>A p.S9* (on ENST00000330513 / NM_001374396.1; = p.S29* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- TLR9 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM270 | c.771G>T p.L257F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TOB2 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- TSEN15 | c.526T>C p.*176Rext*16 (on ENST00000361641 / NM_001300764.2; = p.*172Rext*16 on NM_052965.4) | Nonstop Mutation (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- TTC28 | c.5071A>G p.K1691E | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- UNC5C | c.1970G>T p.C657F | Missense Mutation (SNP) | VAF 73/705 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13D | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- ZNF354C | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ABCA4 | c.9C>T p.F3= | Silent (SNP) | VAF 42/262 reads (16%) | catalogued as rs1352247071, COSV64673778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTC1 | c.513C>T p.Y171= | Silent (SNP) | VAF 37/406 reads (9%) | catalogued as rs145023222, COSV99073267; ClinVar: likely benign / benign; called by muse, mutect2
- ADAMTS10 | c.2793G>A p.P931= | Silent (SNP) | VAF 41/194 reads (21%) | catalogued as COSV54353043; called by muse, mutect2, varscan2
- ADAMTS5 | c.648G>A p.P216= | Silent (SNP) | VAF 71/390 reads (18%) | catalogued as rs778391797, COSV53178060; called by muse, mutect2, varscan2
- ADCK1 | c.1431C>T p.F477= | Silent (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- ADGB | c.384A>G p.E128= | Silent (SNP) | VAF 10/151 reads (7%) | called by muse, mutect2
- ADH1C | c.201C>G p.G67= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- AGBL2 | c.2286G>A p.E762= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- AKAP17A | c.1401C>T p.V467= | Silent (SNP) | VAF 28/352 reads (8%) | catalogued as rs1218486806; called by muse, mutect2
- AMPH | c.1725G>A p.P575= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV100343652; called by muse, mutect2
- ARNT2 | c.672G>A p.Q224= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- ART5 | c.723G>A p.Q241= | Silent (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- ATP2C1 | c.1995T>C p.G665= | Silent (SNP) | VAF 40/382 reads (10%) | called by muse, mutect2, varscan2
- BORCS6 | c.102T>C p.S34= | Silent (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- CBX6 | c.621C>T p.R207= | Silent (SNP) | VAF 27/249 reads (11%) | catalogued as rs1420195465, COSV99327981; called by muse, mutect2, varscan2
- CCDC105 | c.330G>A p.P110= | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- CFAP43 | c.3084C>T p.D1028= | Silent (SNP) | VAF 74/286 reads (26%) | catalogued as rs547940672, COSV53377231; called by muse, mutect2, varscan2
- CMA1 | c.666G>A p.S222= | Silent (SNP) | VAF 12/139 reads (9%) | catalogued as rs142397893; called by muse, mutect2
- COL15A1 | c.2988C>A p.G996= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- COL16A1 | c.1173C>A p.L391= | Silent (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- COL5A1 | c.1590C>T p.G530= | Silent (SNP) | VAF 36/468 reads (8%) | catalogued as rs769010469, COSV65668994; ClinVar: benign / likely benign; called by muse, mutect2
- DBX2 | c.84G>A p.A28= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs772196893, COSV100224319; called by muse, varscan2
- DLGAP3 | c.2136C>T p.H712= | Silent (SNP) | VAF 25/288 reads (9%) | catalogued as rs779200016; called by muse, mutect2
- DNAH10 | c.2655C>T p.D885= (on ENST00000409039; = p.D824= on NM_207437.3) | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs769392126, COSV68993076; called by muse, mutect2, varscan2
- DPP6 | c.108C>T p.D36= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV66719235; called by muse, mutect2
- EHD2 | c.168C>T p.D56= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs1452151591; called by muse, mutect2
- EPHA3 | c.255C>T p.N85= | Silent (SNP) | VAF 15/359 reads (4%) | catalogued as COSV60716477; called by muse, mutect2
- ESRP2 | c.1395C>G p.P465= (on ENST00000565858 / NM_001365264.1; = p.P455= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.1533C>T p.T511= | Silent (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- FBXO34 | c.297C>T p.G99= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs370719777; called by muse, mutect2
- FEM1B | c.1167T>A p.A389= | Silent (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- GATA3 | c.741C>T p.F247= | Silent (SNP) | VAF 26/262 reads (10%) | catalogued as rs1176612736, COSV100651205; called by muse, mutect2, varscan2
- GJC2 | c.1227C>T p.P409= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs770928675, COSV64513126; called by muse, mutect2, varscan2
- HOXA5 | c.30C>T p.C10= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV56072557; called by muse, mutect2
- HRH3 | c.405G>A p.S135= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs754872125; called by muse, mutect2, varscan2
- IBSP | c.789C>T p.Y263= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as rs748156515, COSV56895150; called by muse, mutect2, varscan2
- IGHMBP2 | c.2811C>T p.R937= | Silent (SNP) | VAF 37/352 reads (11%) | catalogued as rs752860280; called by muse, mutect2, varscan2
- IL2 | c.321C>T p.S107= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs779955038; called by muse, mutect2, varscan2
- KALRN | c.5691C>T p.S1897= (on ENST00000360013 / NM_001024660.4; = p.S200= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- KCND3 | c.843C>T p.D281= | Silent (SNP) | VAF 42/402 reads (10%) | catalogued as rs1287255718, COSV56176900; called by muse, mutect2, varscan2
- KCNG1 | c.1173C>T p.F391= | Silent (SNP) | VAF 22/300 reads (7%) | catalogued as rs1457867165, COSV65368880; called by muse, mutect2
- KCNQ2 | c.213C>T p.N71= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- KLHL29 | c.1779G>A p.Q593= | Silent (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- LAMA3 | c.987G>A p.T329= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as rs926067937; called by muse, mutect2, varscan2
- LILRA2 | c.1023C>T p.T341= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as rs1165941135; called by muse, mutect2, varscan2
- LMOD2 | c.732G>T p.T244= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- LRP1B | c.2622C>T p.S874= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as rs775728525, COSV63341565; called by muse, mutect2, varscan2
- LRP1B | c.891C>A p.L297= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV67214112; called by muse, mutect2, varscan2
- LRRC4B | c.393C>T p.N131= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs750186464; called by muse, mutect2, varscan2
- MILR1 | c.828T>C p.Y276= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs782523103; called by muse, mutect2, varscan2
- MRPL41 | c.291G>T p.A97= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- MUC6 | c.2427C>T p.C809= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs368446728; called by muse, mutect2, varscan2
- NDUFV1 | c.1227C>T p.I409= | Silent (SNP) | VAF 31/327 reads (9%) | catalogued as rs781193720, COSV59596800; called by muse, mutect2, varscan2
- NES | c.3030C>T p.G1010= | Silent (SNP) | VAF 59/252 reads (23%) | catalogued as rs1454642034; called by muse, mutect2, varscan2
- NFASC | c.2199C>T p.D733= (on ENST00000339876 / NM_001378329.1; = p.D729= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs752314030, COSV58380168; called by muse, mutect2, varscan2
- NHSL1 | c.2934G>A p.P978= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs1158513307, COSV58682512; called by muse, mutect2, varscan2
- NPFFR2 | c.117C>T p.R39= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV58148681; called by muse, mutect2, varscan2
- OR56A3 | c.828G>T p.V276= | Silent (SNP) | VAF 40/282 reads (14%) | called by mutect2, varscan2
- PARP9 | c.2328G>A p.P776= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as rs755622009; called by muse, mutect2, varscan2
- PCDH10 | c.1872C>T p.N624= | Silent (SNP) | VAF 42/319 reads (13%) | catalogued as rs540013540, COSV52088507; called by muse, mutect2, varscan2
- PCDH12 | c.2475G>A p.T825= | Silent (SNP) | VAF 44/470 reads (9%) | catalogued as rs755687030; called by muse, mutect2
- PCDHB12 | c.651C>T p.G217= | Silent (SNP) | VAF 32/277 reads (12%) | catalogued as rs561631495, COSV53393325; called by muse, mutect2, varscan2
- PCDHGA11 | c.1569T>C p.Y523= | Silent (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- PIK3R5 | c.1687C>A p.R563= | Silent (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- PINLYP | c.246C>T p.S82= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs1166859635; called by muse, mutect2, varscan2
- PITPNM3 | c.2808C>T p.A936= | Silent (SNP) | VAF 55/264 reads (21%) | catalogued as rs745544061; called by muse, mutect2, varscan2
- PLD1 | c.2643T>C p.H881= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- POU2AF1 | c.318C>T p.T106= | Silent (SNP) | VAF 33/295 reads (11%) | catalogued as rs139129319, COSV101260640; called by muse, mutect2, varscan2
- PSG7 | c.1173C>G p.L391= | Silent (SNP) | VAF 17/280 reads (6%) | called by muse, mutect2
- PTPRN2 | c.783C>A p.G261= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs1012125743; called by muse, mutect2
- PTX3 | c.279C>T p.G93= | Silent (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- RAD18 | c.1368C>T p.A456= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- RASAL1 | c.1095G>A p.E365= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs1352628246; called by muse, mutect2, varscan2
- RASAL3 | c.57G>A p.P19= | Silent (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- RELN | c.3198G>A p.P1066= | Silent (SNP) | VAF 62/672 reads (9%) | catalogued as rs767180170, COSV100634141; ClinVar: likely benign; called by muse, mutect2
- RETREG2 | c.330A>G p.S110= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- SELENOV | c.540G>A p.S180= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- SH2B3 | c.168G>A p.A56= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs1322124956; called by muse, varscan2
- SIAH2 | c.846G>T p.S282= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- SLC22A16 | c.1284C>A p.A428= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- SLC5A9 | c.1491G>T p.L497= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1581C>T p.H527= | Silent (SNP) | VAF 47/536 reads (9%) | catalogued as rs1358534316, COSV100999984; called by muse, mutect2
- SMARCA4 | c.984G>C p.P328= | Silent (SNP) | VAF 28/234 reads (12%) | called by mutect2, varscan2
- SPTBN2 | c.1281C>T p.A427= | Silent (SNP) | VAF 28/256 reads (11%) | catalogued as rs374787500; ClinVar: uncertain significance; called by muse, mutect2
- STAB1 | c.1743C>T p.H581= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as rs140934139; called by muse, mutect2
- TIE1 | c.723C>T p.D241= | Silent (SNP) | VAF 42/250 reads (17%) | catalogued as rs191640035; called by muse, mutect2, varscan2
- TPR | c.5427T>A p.P1809= | Silent (SNP) | VAF 12/217 reads (6%) | called by muse, mutect2
- UGT1A7 | c.744A>G p.T248= | Silent (SNP) | VAF 48/245 reads (20%) | catalogued as rs771388089; called by muse, mutect2, varscan2
- UNC79 | c.1269C>T p.H423= (on ENST00000393151 / NM_001346218.2; = p.H246= on NM_020818.5) | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- WDR81 | c.4959C>T p.C1653= (on ENST00000409644 / NM_001163809.2; = p.C602= on NM_152348.4) | Silent (SNP) | VAF 48/236 reads (20%) | catalogued as rs374175675; called by muse, mutect2, varscan2
- WWTR1 | c.207G>A p.S69= | Silent (SNP) | VAF 49/276 reads (18%) | called by muse, mutect2, varscan2
- ZNF114 | c.861C>T p.N287= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs200721350, COSV59943536; called by muse, mutect2, varscan2
- ZNF28 | c.348C>T p.I116= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+7139T>C | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- AC136604.1 | n.476G>C | RNA (SNP) | VAF 32/352 reads (9%) | called by muse, mutect2
- AKR1D1 | c.*49G>A | 3'UTR (SNP) | VAF 11/92 reads (12%) | catalogued as rs368713869; called by muse, mutect2
- ARHGEF3 | c.97-1238C>T | Intron (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- ASS1 | c.773+67G>A | Intron (SNP) | VAF 85/505 reads (17%) | catalogued as rs777414511; called by muse, mutect2, varscan2
- ATP10D | c.1635+13G>T | Intron (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- C16orf89 | c.-25G>T | 5'UTR (SNP) | VAF 53/369 reads (14%) | called by muse, mutect2, varscan2
- CARMIL3 | c.*32C>T | 3'UTR (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- COL1A2 | c.2403+34C>T | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- EYS | c.1767-6438G>T | Intron (SNP) | VAF 34/340 reads (10%) | called by mutect2, varscan2
- FZD4 | c.-37del | 5'UTR (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- GOLGA8N | c.349-76G>A | Intron (SNP) | VAF 15/274 reads (5%) | catalogued as rs1293176193; called by muse, mutect2
- GORAB | c.*43A>G | 3'UTR (SNP) | VAF 24/258 reads (9%) | catalogued as rs374315251; called by muse, mutect2
- GPR88 | c.-10G>A | 5'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8291G>A | Intron (SNP) | VAF 25/254 reads (10%) | catalogued as rs750404101; called by muse, mutect2, varscan2
- LINC01546 | n.458C>A | RNA (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- LRIT2 | c.893-173G>T | Intron (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- MAMLD1 | c.*496G>A | 3'UTR (SNP) | VAF 29/146 reads (20%) | catalogued as rs1214795542; called by muse, mutect2, varscan2
- MAU2 | c.*229T>C | 3'UTR (SNP) | VAF 48/261 reads (18%) | called by muse, mutect2, varscan2
- MIR124-2 | n.37G>A | RNA (SNP) | VAF 23/189 reads (12%) | catalogued as rs1261326747; called by muse, mutect2, varscan2
- MIR514A1 | n.75G>T | RNA (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- MIR9-1 | chr1:156420302 C>T | 3'Flank (SNP) | VAF 19/222 reads (9%) | catalogued as rs777377928; called by muse, mutect2
- MLXIPL | c.619-16G>A | Intron (SNP) | VAF 22/324 reads (7%) | catalogued as rs782729011; called by muse, mutect2
- MUCL3 | c.946+621G>A | Intron (SNP) | VAF 18/170 reads (11%) | catalogued as rs771240132, COSV58516977; called by muse, mutect2, varscan2
- NEURL3 | c.514+67G>A | Intron (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- NLGN4Y | c.*1618G>T | 3'UTR (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- NPVF | c.*8G>T | 3'UTR (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- PAXIP1 | c.325-2776C>A | Intron (SNP) | VAF 36/194 reads (19%) | catalogued as rs756393758; called by muse, mutect2, varscan2
- PENK | c.138+135G>A | Intron (SNP) | VAF 22/270 reads (8%) | catalogued as COSV59243591; called by muse, mutect2
- PTPRN2 | c.2344+5852G>T | Intron (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- SLC26A3 | c.-35G>T | 5'UTR (SNP) | VAF 28/282 reads (10%) | catalogued as rs1450229987; called by muse, mutect2
- SP110 | c.1707-16G>A | Intron (SNP) | VAF 55/318 reads (17%) | catalogued as rs1218400464; called by muse, mutect2, varscan2
- SPAG9 | c.590+553G>A | Intron (SNP) | VAF 39/139 reads (28%) | catalogued as rs1465462214; called by muse, mutect2, varscan2
- SPATA31C1 | n.3530C>T | RNA (SNP) | VAF 80/438 reads (18%) | catalogued as rs771953119; called by muse, mutect2, varscan2
- SPEG | c.2882-1083C>T | Intron (SNP) | VAF 32/323 reads (10%) | catalogued as rs762424868, COSV56680928; called by muse, mutect2, varscan2
- STK31 | c.-24C>T | 5'UTR (SNP) | VAF 30/261 reads (11%) | catalogued as rs772803310; called by muse, mutect2
- TPRX2P | n.291G>A | RNA (SNP) | VAF 30/340 reads (9%) | catalogued as rs749296712; called by muse, mutect2
- Unknown | chr21:16071390 A>G | IGR (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
